Somatic mutation profile of tumor specimen 0DV4J7 from CCDI case PBCMID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 16.7 years (6,113 days).
Specimen 0DV4J7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3165c538-3899-4534-873e-ee1c90cd2384.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dce01d5-edb3-4a6f-80bc-61a456f2f409

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 2, Splice Region 1, Intron 1, 3'UTR 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 194/515 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3808C>T p.R1270* | Nonsense Mutation (SNP) | VAF 119/310 reads (38%) | catalogued as rs575627531, CM095220, COSV66072346; called by muse, mutect2, varscan2
- GPR50 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 293/721 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs775520411, COSV54442949; called by muse, mutect2, varscan2
- SYT13 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 273/794 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014628126; called by muse, mutect2, varscan2
- AC006059.2 | c.2055C>A p.T685= | Splice Region (SNP) | VAF 343/967 reads (35%) | called by muse, mutect2, varscan2
- CEACAM4 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 165/430 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLEC4C | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 195/506 reads (39%) | called by muse, mutect2, varscan2
- OR51F1 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 138/475 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF449 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 261/690 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR39 | c.1296G>A p.E432= | Silent (SNP) | VAF 38/698 reads (5%) | called by muse, mutect2
- OR14C36 | c.399C>T p.I133= | Silent (SNP) | VAF 62/659 reads (9%) | catalogued as rs150366522, COSV58602888; called by muse, mutect2
- TSC22D2 | c.1452G>T p.P484= | Silent (SNP) | VAF 32/390 reads (8%) | called by muse, mutect2
- CSNK1A1L | c.*9G>A | 3'UTR (SNP) | VAF 27/358 reads (8%) | catalogued as COSV101131077; called by muse, mutect2
- RIMS1 | c.1679-16630G>A | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- SCP2D1 | chr20:18809809 C>T | 5'Flank (SNP) | VAF 50/756 reads (7%) | catalogued as rs764118953; called by muse, mutect2
- ZXDA | c.-82G>A | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
